Somatic mutation profile of tumor specimen TCGA-55-8513-01A (aliquot TCGA-55-8513-01A-11D-2393-08) from TCGA case TCGA-55-8513, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.4 years (28,284 days).
Specimen TCGA-55-8513-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 233bcb50-adfa-42f6-a9ff-7ee44cc44d3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8513-10A (Blood Derived Normal), aliquot TCGA-55-8513-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1feeceed-eebc-4e63-a927-967957966279

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FNDC7 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99601667; called by muse, mutect2
